Somatic mutation profile of tumor specimen BA2595D (aliquot aq-BA2595D) from BEATAML1.0 case 2148, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.8 years (24,016 days).
Specimen BA2595D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4610998d-4116-49ef-881c-60d61db15d27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2433D (Solid Tissue Normal), aliquot aq-BA2433D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5acc3c0-bfb4-44e4-a9d7-a68501596069

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRACD | c.857C>A p.A286E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51732740; called by muse, mutect2
- PTPRD | c.4187G>A p.R1396Q | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781289256, COSV61931771; called by muse, varscan2
- CDC42EP1 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- GCGR | c.212C>A p.T71N | Missense Mutation (SNP) | VAF 112/218 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.698); called by mutect2, varscan2
- KCNJ14 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.12); called by muse, varscan2
- ZNF287 | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHH | c.1104G>T p.A368= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
